Surgical pathology report (de-identified scan), TCGA case TCGA-K7-A5RF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K7-A5RF-01A (Primary Tumor).

[page 1 of 5]
Gender

M

Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Final

Results

1CB-0-3

Final

Source of Specimen

- A. GALLBLADDER-
- B. CORE LIVER BIOPSY FS-
- C. CORE LIVER BIOPSY NFS-
- D. SEGMENT 7 OF LIVER FS-
- E. SEGMENT 7 OF LIVER NFS-
- F. LEFT LOBE LIVER BIOPSY-

carcinoma hepatocellular, NOS 8/10/13
Site: liver C22-0

fw
2/17/13

FINAL DIAGNOSIS:

- A. GALLBLADDER-
- MILD CHRONIC INFLAMMATION WITH FOCAL CHOLESTEROSIS.
- B. CORE LIVER BIOPSY FS-
- SEE PART "C".
- C. CORE LIVER BIOPSY NFS-
- HEPATOCELLULAR CARCINOMA, WELL DIFFERENTIATED, ONE FRAGMENT.

CIRRHOSIS, ONE FRAGMENT.

MILD STAINABLE IRON IN KUPFFER CELLS.

NOTE: A CIRRHOTIC NODULE WITH FOCAL CYTOLOGIC ATYPYIA IS SEEN ON THE ORIGINAL FROZEN SECTION SLIDE. THE PERMANENT SECTION OF THE FROZEN SECTION REMNANT AS WELL AS SPECIMEN "C" SHOW ONE FRAGMENT COMPOSED OF ATYPICAL HEPATOCYTES WITH DISRUPTED RETICULIN FRAMEWORK WHICH ARE POSITIVE FOR GLYPICAN-3. CEA POLYCLONAL IS ALSO POSITIVE IN A CANALICULAR PATTERN. THESE FINDINGS SUPPORT THE ABOVE DIAGNOSIS.

TRICHROME, RETICULIN AND IRON STAINS EXAMINED.

Prepare

[page 2 of 5]
Internal positive elements were examined and/or appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

D. SEGMENT 7 OF LIVER FS-
SEE PART "E".

E. SEGMENT 7 OF LIVER NFS-
SMALL CELL DYSPLASTIC NODULE WITH MINUTE SCATTERED FOCI WITH IMMUNOPROFILE SUGGESTIVE OF EARLY EVOLVING HEPATOCELLULAR CARCINOMA, see note.

CIRRHOSIS WITH MILD STEATOSIS CONSISTENT WITH CHRONIC HEPATITIS C, GRADE 2/4, STAGE 4/4.

NO CARCINOMA SEEN AT SPECIMEN MARGINS.

NOTE: THE RETICULIN STAIN HIGHLIGHTS A PRESERVED FRAMEWORK WITH RARE FOCI OF THICKENED HEPATOCYTIC PLATES. THESE MINUTE FOCI ARE WEAKLY POSITIVE FOR GLYPICAN-3. THE HISTOLOGY IN ADDITION TO THESE FINDINGS SUPPORT THE ABOVE DIAGNOSIS.

Internal positive elements were examined and/or appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

F. LEFT LOBE LIVER BIOPSY-
CIRRHOSIS WITH MILD STEATOSIS CONSISTENT WITH CHRONIC HEPATITIS C, GRADE 2/4, STAGE 4/4.

MILD STAINABLE IRON IN KUPFFER CELLS.

TRICHROME, RETICULIN AND IRON STAINS EXAMINED.

Internal positive elements were examined and/or appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

Comment

CASE REVIEWED INTRADEPARTMENTALLY.

Signature

(Case signed

Signed Others

Frozen Section

A. CORE LIVER BIOPSY: CONSISTENT WITH CIRRHOTIC LIVER WITH

Prepared

[page 3 of 5]
REGENERATING NODULE. LOW GRADE ATYPIA PRESENT, NOT DIAGNOSTIC OF HEPATOCELLULAR CARCINOMA.

(Frozen Section Signed

D. SEGMENT 7 OF LIVER: CIRRHOTIC LIVER WITH ABNORMAL NODULE.

Frozen section

(Frozen Section Signed

Case Clinical Information
HEPATOCELLULAR CARCINOMA

Gross Description

- A. Received in formalin labeled with the patient's name and "gallbladder" consists of a dilated cholecystectomy specimen measuring in length 9.0 cm with a bile stained serosa. The cystic duct measures 1.5 cm in length. The gallbladder mucosa has a diffuse bile staining with a velvety appearance. The lumen contains a large amount of viscous bile material. No lesions or polyps are identified. No stones are noted in the lumen or in the container. A representative section of cystic duct margin and body of the gallbladder submitted in A1.
- B. Received in formalin labeled with the patient's name and "core liver biopsy FS" consists of two 0.4 cm core tissue remnants. Entirely submitted wrapped in B1.
- C. Received in formalin labeled with the patient's name and "core liver biopsy NFS" consists of two fragments of tan tissue each measuring 0.3 cm. Specimen is wrapped and submitted in C1.
- D. Received in formalin labeled with the patient's name and "segment 7 of liver FS" consists of a 2.5 x 2 x 0.3 cm frozen section tissue remnant with the surface revealing a hemorrhagic circumscribed 0.4 cm area. Entirely submitted in D1.
- E. Received in formalin labeled with the patient's name and "segment 7 of liver NFS" consists of a 160 gram partial hepatectomy specimen that has been previously serially sectioned. When reconstructed overall dimensions of the specimen measure 9.5 x 9.5 x 6.6 cm. The capsule is intact it is tan and diffuse micro-nodularity consistent with cirrhosis. The margin has a shaggy focally hemorrhagic appearance. Also the specimen reveals a 3 x 3.0 cm area of sectioned tissue. These are

Prepared: _____

[page 4 of 5]
separate in the container. The cut surface reveals a single blue nylon suture and may represent area of tumor. This area measures 2.0 cm to the resection margin. On the remaining sections in the container one reveals a 1.8 cm circumscribed nodule. This nodule measures to the capsule 0.2 cm and to the resection margin 1.0 cm. The remainder of the cut surface has a uniform nodular consistency consistent with a cirrhotic liver parenchyma. Representative sections of the specimen are submitted as follows: E1-E3=entire nodule from separate fragments; E4=remainder of parenchyma at area of blue suture; E5-E6=resection margin to the suture; E7-E8=representative sections away from the suture. Additional sections from the marked sutured area in E9-E11.

F. Received in formalin labeled with the patient's name and "left lobe liver biopsy" consists of a 1.5 cm core of tissue. Wrapped and submitted in F1

Physicians

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. LIV NB BLOCK
H&E X3 TRICHROME FE RETIC CEA POLYCLONAL GLYP-3
- D. AA ROUTINE H&E X1 BLOCK
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.1
H&E X1 GLYP-3 RETIC
- E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.4
H&E X1 GLYP-3 RETIC
- E. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.7
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.8
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.10

Prepared: _____

[page 5 of 5]
H&E X1
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1
E. AA ROUTINE H&E X1 BLOCK.12
H&E X1
F. LIV NB BLOCK
H&E X3 TRICHROME FE RETIC

Prepared: _____

Source: NCI Genomic Data Commons file 3cde362c-72f9-4f9d-8013-e290a3ce9084 (TCGA-K7-A5RF.04C26B7B-66EE-4F20-A059-52E19557C268.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).